Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6827, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6827-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 3

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: **Excision of lesion – Lesion of the upper lip**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Lesion of the upper lip and oral vestibule on the right side.**

Examination performed on:

Macroscopic description:

A fragment of the lip sized 2.8 x 2.3 x 1.9 cm; a whitish tumour sized 1.7 x 1.7 x 1.2 cm found on the back surface .

Margins: upper – belowe 0.1 cm, left – 0,3 cm, right –0,3 cm.

Histopathological Diagnosis:

Carcinoma planoepitheliale akeratodes (G3). Squamous non-keratinized carcinoma.

Margins of normal tissues as in the macroscopic description.

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 40cb9280-8d22-4138-8420-d8b480b4d374 (TCGA-D6-6827.295B2B52-0F43-4FD8-9BB7-A72205563BDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).